Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-5671, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-5671-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY:

RENAL CELL CARCINOMA (2.7 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE
(100% CLEAR CELLS),
FUHRMAN NUCLEAR GRADE 3, CONFINED TO THE KIDNEY.

Margins of resection free of tumor.

Adrenal cortical adenoma (1.7 cm maximum dimension).

COMMENT

The renal cell carcinoma in the left kidney does not invade into the perinephric adipose tissue, renal sinus adipose tissue, or the renal vein.

There is no metastatic renal cell carcinoma in the adrenal gland.

GROSS DESCRIPTION

(A) LEFT KIDNEY, STERILE - A radical nephrectomy specimen (20.0 x 10.0 x 8.0 cm) with an attached 2.5 x 0.4 cm segment of ureter, 1.5 x 0.4 cm segment of renal vein and 7.5 x 6.5 cm unremarkable adipose tissue.

A fairly well circumscribed tumor (2.7 x 2.7 x 2.0 cm) is located on the anterior aspect of the mid-portion of the kidney. The tumor is well-circumscribed and abuts the renal sinus and perinephric adipose tissue. The renal vein is free of tumor. The surface of the tumor is yellow-tan and hemorrhagic.

No other lesions are identified within the kidney parenchyma, which is otherwise unremarkable. The adrenal gland measures 3.5 x 2.5 cm and shows a single 1.7 cm solitary nodule. The nodule has a bright yellow-orange surface and fails to demonstrate any significant necrosis.

INK CODE: Blue-perinephric adipose tissue.

SECTION CODE: A1, ureter, renal vein and artery, en face; A2-A8, renal mass totally embedded (A2-A4, tumor and renal sinus; A5-A8, tumor and perinephric adipose tissue); A9-A12, adrenal tumor totally embedded; A13, unremarkable kidney parenchyma. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123, T-B3000, M-83700

"Some tests reported here may have been developed and performance characteristics determined by [REDACTED] Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Source: NCI Genomic Data Commons file 639e92d0-b4a2-4866-9095-ff487d88e09b (TCGA-CJ-5671.925DA9B8-7137-4F44-9F6D-BFF244B59762.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).